Somatic mutation profile of tumor specimen 0DQHB1 from CCDI case PBCFAK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 14.4 years (5,269 days).
Specimen 0DQHB1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6aad304c-1ef8-4056-a1d2-dab9e4f2e670.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f49eacdb-2ef5-46e0-bc30-e2f4c677f2a5

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 3, Splice Region 1, Silent 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD1 | c.5123G>A p.R1708Q | Missense Mutation (SNP) | VAF 169/498 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs1293161341, COSV99399522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A1 | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 147/746 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866316555; called by muse, mutect2
- ETV5 | c.911-7C>G | Splice Region (SNP) | VAF 36/620 reads (6%) | catalogued as rs775687516; called by muse, mutect2
- GZMK | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 55/721 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763434219; called by muse, mutect2
- HDAC9 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 34/818 reads (4%) | catalogued as COSV67771291; called by muse, mutect2
- SAMHD1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 265/747 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs147891080; called by muse, mutect2, varscan2
- SLC7A13 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 279/668 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as COSV52536294; called by mutect2, varscan2
- SPOCD1 | c.3404G>A p.R1135H | Missense Mutation (SNP) | VAF 79/535 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs762121428; called by muse, mutect2, varscan2
- NLRP10 | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR8J1 | c.641T>A p.V214D | Missense Mutation (SNP) | VAF 36/788 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTPRCAP | c.425A>G p.Q142R | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF510 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 204/538 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, varscan2
- BTN3A2 | c.927G>A p.Q309= | Silent (SNP) | VAF 22/439 reads (5%) | catalogued as COSV100709734; called by muse, mutect2
- EIF4B | c.152-14T>C | Intron (SNP) | VAF 122/279 reads (44%) | called by muse, mutect2, varscan2
- ROBO3 | c.3533+17T>C | Intron (SNP) | VAF 35/517 reads (7%) | called by muse, mutect2
- RPL11 | c.393+91T>G | Intron (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- SLC23A2 | c.-85C>T | 5'UTR (SNP) | VAF 26/326 reads (8%) | catalogued as rs555686646; called by muse, mutect2
